Somatic mutation profile of tumor specimen 0DJVPQ from CCDI case PBBXJD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.2 years (1,168 days).
Specimen 0DJVPQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e486b49-493a-4362-90ed-45e8f13d503e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJVPB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e1b4841-3cfd-4ba9-8988-74651f809caf

The open-access MAF lists 2 somatic variants for this specimen: 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEPDC7 | c.1008G>A p.T336= (on ENST00000241051 / NM_001077242.2; = p.T327= on NM_139160.2) | Silent (SNP) | VAF 112/479 reads (23%) | catalogued as rs183771544; called by muse, mutect2, varscan2
- SORBS2 | c.684+7747G>A | Intron (SNP) | VAF 267/636 reads (42%) | catalogued as rs999052328, COSV99509732; called by muse, mutect2, varscan2
